Somatic mutation profile of tumor specimen MMRF_1785_1_BM_CD138pos (aliquot MMRF_1785_1_BM_CD138pos_T1_KBS5U_K11347) from MMRF case MMRF_1785, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 63.6 years (23,227 days).
Specimen MMRF_1785_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ea2e287a-6315-407b-8801-7cecea1af916.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1785_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1785_1_PB_Whole_C2_KBS5U_K11348; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f273dc72-3e30-4410-ab8f-0094aad0cef5

The open-access MAF lists 120 somatic variants for this specimen: 49 protein-altering or splice-affecting, 18 silent, 53 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 42, 3'UTR 30, Silent 18, Intron 14, Nonsense Mutation 3, Frame Shift Del 3, RNA 3, 5'UTR 2, 3'Flank 2, 5'Flank 2, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CAPN1 | c.1991C>T p.S664L | Missense Mutation (SNP) | VAF 59/353 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.085); catalogued as rs375107477; called by muse, mutect2, varscan2
- CDCP1 | c.1057C>T p.R353* | Nonsense Mutation (SNP) | VAF 38/80 reads (48%) | catalogued as rs750320472, COSV56106075; called by muse, mutect2, varscan2
- CNTN2 | c.1888C>T p.R630C | Missense Mutation (SNP) | VAF 134/200 reads (67%) | SIFT deleterious (0.01); PolyPhen benign (0.329); catalogued as rs574231253, COSV59347924, COSV59352225; called by muse, mutect2, varscan2
- DIS3 | c.1985T>G p.M662R | Missense Mutation (SNP) | VAF 26/28 reads (93%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV66705805; called by muse, mutect2, varscan2
- DNAH1 | c.6371G>A p.R2124H | Missense Mutation (SNP) | VAF 142/258 reads (55%) | SIFT deleterious (0); PolyPhen possibly damaging (0.51); catalogued as rs748843812, COSV70229899; called by muse, mutect2, varscan2
- FRMPD3 | c.823C>T p.R275C | Missense Mutation (SNP) | VAF 96/96 reads (100%) | SIFT deleterious (0); PolyPhen possibly damaging (0.741); catalogued as rs1373735369; called by muse, mutect2, varscan2
- HIC2 | c.187G>A p.V63I | Missense Mutation (SNP) | VAF 109/249 reads (44%) | SIFT tolerated (1); PolyPhen benign (0.068); catalogued as rs367902699; called by muse, mutect2, varscan2
- HPN | c.721G>A p.G241R | Missense Mutation (SNP) | VAF 66/140 reads (47%) | SIFT tolerated (0.18); PolyPhen benign (0.158); catalogued as rs758071341, COSV52882538, COSV52886631; called by muse, mutect2, varscan2
- ICAM3 | c.668del p.P223Rfs*21 | Frame Shift Del (DEL) | VAF 6/43 reads (14%) | catalogued as rs759151580; called by pindel, varscan2
- IGLV3-1 | c.132T>G p.D44E | Missense Mutation (SNP) | VAF 91/173 reads (53%) | SIFT tolerated (0.24); PolyPhen benign (0.027); catalogued as rs373697673; called by muse, mutect2, varscan2
- MX2 | c.1355A>G p.N452S | Missense Mutation (SNP) | VAF 34/68 reads (50%) | SIFT tolerated (0.56); PolyPhen benign (0.241); catalogued as rs1292240291; called by muse, mutect2, varscan2
- RIC8B | c.1360G>T p.A454S | Missense Mutation (SNP) | VAF 78/167 reads (47%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.998); catalogued as rs1401581350; called by muse, mutect2, varscan2
- TRAF3 | c.1429A>T p.I477F | Missense Mutation (SNP) | VAF 24/106 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV61025011; called by muse, varscan2
- ARHGAP21 | c.4730T>G p.L1577W | Missense Mutation (SNP) | VAF 139/272 reads (51%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.94); called by muse, mutect2, varscan2
- BUB1 | c.1159C>T p.P387S | Missense Mutation (SNP) | VAF 34/74 reads (46%) | SIFT tolerated (0.29); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- COTL1 | c.139C>A p.H47N | Missense Mutation (SNP) | VAF 17/35 reads (49%) | SIFT deleterious (0.02); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- DDX23 | c.2425C>T p.L809F | Missense Mutation (SNP) | VAF 37/81 reads (46%) | SIFT tolerated (0.52); PolyPhen possibly damaging (0.606); called by muse, mutect2, varscan2
- DUSP2 | c.239T>A p.L80Q | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- FER1L5 | c.2707A>G p.N903D (on ENST00000623019; = p.N908D on NM_001293083.2) | Missense Mutation (SNP) | VAF 6/86 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.536); called by muse, mutect2
- GALNT14 | c.1322C>T p.T441I | Missense Mutation (SNP) | VAF 64/248 reads (26%) | SIFT tolerated (0.48); PolyPhen benign (0); called by muse, mutect2, varscan2
- HMCN1 | c.13698G>C p.K4566N | Missense Mutation (SNP) | VAF 69/263 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- HS3ST5 | c.520T>A p.S174T | Missense Mutation (SNP) | VAF 12/394 reads (3%) | SIFT tolerated (0.13); PolyPhen benign (0.221); called by muse, mutect2
- JAM2 | c.214T>C p.F72L | Missense Mutation (SNP) | VAF 40/86 reads (47%) | SIFT tolerated (0.08); PolyPhen benign (0.106); called by muse, mutect2, varscan2
- KLK12 | c.206G>C p.W69S | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT tolerated (0.72); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- LMF1 | c.1355C>A p.P452H | Missense Mutation (SNP) | VAF 106/228 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LRP1B | c.2480A>T p.D827V | Missense Mutation (SNP) | VAF 36/186 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.368); called by muse, mutect2, varscan2
- LTC4S | c.311+1del | Frame Shift Del (DEL) | VAF 6/13 reads (46%) | called by mutect2, varscan2
- MCF2 | c.1274C>A p.A425E | Missense Mutation (SNP) | VAF 95/98 reads (97%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.594); called by muse, mutect2, varscan2
- MEP1B | c.1308T>G p.N436K | Missense Mutation (SNP) | VAF 140/275 reads (51%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- MGAT4A | c.696A>G p.V232= | Splice Region (SNP) | VAF 82/166 reads (49%) | called by muse, mutect2, varscan2
- MITD1 | c.223A>C p.I75L | Missense Mutation (SNP) | VAF 55/114 reads (48%) | SIFT tolerated (0.51); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- MYO1D | c.375_376del p.Q127Efs*5 | Frame Shift Del (DEL) | VAF 50/107 reads (47%) | called by mutect2, pindel, varscan2
- OR52E4 | c.538T>C p.Y180H | Missense Mutation (SNP) | VAF 86/183 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- OTX1 | c.428C>G p.S143C | Missense Mutation (SNP) | VAF 64/206 reads (31%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.7); called by muse, mutect2, varscan2
- PCDHGC5 | c.567G>T p.K189N | Missense Mutation (SNP) | VAF 68/138 reads (49%) | SIFT tolerated (0.13); PolyPhen benign (0.403); called by muse, mutect2, varscan2
- POGK | c.697G>T p.D233Y | Missense Mutation (SNP) | VAF 89/393 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.917); called by muse, mutect2, varscan2
- ROR1 | c.1318C>G p.Q440E | Missense Mutation (SNP) | VAF 34/206 reads (17%) | SIFT tolerated (0.29); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- SAMD15 | c.544G>T p.E182* | Nonsense Mutation (SNP) | VAF 83/158 reads (53%) | called by muse, mutect2, varscan2
- SLCO1B3 | c.955A>T p.T319S | Missense Mutation (SNP) | VAF 24/47 reads (51%) | SIFT tolerated (0.64); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- SMG1 | c.9859A>C p.N3287H | Missense Mutation (SNP) | VAF 29/75 reads (39%) | SIFT tolerated (0.12); PolyPhen benign (0.123); called by muse, mutect2, varscan2
- SRFBP1 | c.655C>G p.Q219E | Missense Mutation (SNP) | VAF 20/244 reads (8%) | SIFT tolerated (0.17); PolyPhen benign (0.006); called by muse, mutect2
- TM7SF3 | c.1229T>A p.V410D | Missense Mutation (SNP) | VAF 30/71 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); called by muse, mutect2, varscan2
- TP53INP1 | c.115A>G p.T39A | Missense Mutation (SNP) | VAF 12/113 reads (11%) | SIFT tolerated (0.45); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TRAF3 | c.1474C>T p.Q492* | Nonsense Mutation (SNP) | VAF 75/123 reads (61%) | called by muse, varscan2
- TRPM2 | c.1249A>T p.T417S | Missense Mutation (SNP) | VAF 29/68 reads (43%) | SIFT tolerated (0.09); PolyPhen benign (0.166); called by muse, mutect2, varscan2
- XAF1 | c.624A>C p.K208N | Missense Mutation (SNP) | VAF 105/205 reads (51%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.541); called by muse, mutect2, varscan2
- ZBTB26 | c.802G>A p.G268S | Missense Mutation (SNP) | VAF 53/129 reads (41%) | SIFT tolerated (0.49); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ZBTB46 | c.1535C>T p.P512L | Missense Mutation (SNP) | VAF 24/51 reads (47%) | SIFT tolerated, low confidence (0.81); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZFYVE16 | c.4487G>A p.G1496D | Missense Mutation (SNP) | VAF 46/95 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- APOB | c.5382A>C p.V1794= | Silent (SNP) | VAF 72/251 reads (29%) | called by muse, mutect2, varscan2
- C9orf131 | c.435C>T p.G145= | Silent (SNP) | VAF 142/310 reads (46%) | called by muse, mutect2, varscan2
- CNPY2 | c.228C>T p.A76= | Silent (SNP) | VAF 44/95 reads (46%) | called by muse, mutect2, varscan2
- GPC3 | c.81G>C p.P27= | Silent (SNP) | VAF 3/51 reads (6%) | catalogued as rs1484069125, COSV100892796; called by muse, mutect2
- HFM1 | c.2281T>C p.L761= | Silent (SNP) | VAF 34/57 reads (60%) | catalogued as COSV54020377; called by muse, mutect2, varscan2
- HMCN1 | c.9168A>C p.P3056= | Silent (SNP) | VAF 172/249 reads (69%) | called by muse, mutect2, varscan2
- IGHJ5 | c.21C>T p.G7= | Silent (SNP) | VAF 27/29 reads (93%) | catalogued as rs1407556441; called by muse, varscan2
- IGHV4-39 | c.150C>G p.V50= | Silent (SNP) | VAF 8/67 reads (12%) | catalogued as rs750408388; called by muse, varscan2
- IGLL5 | c.114G>T p.L38= | Silent (SNP) | VAF 28/49 reads (57%) | catalogued as rs556230331, COSV73249618, COSV73250730; called by muse, mutect2, varscan2
- IGLV3-1 | c.255T>C p.S85= | Silent (SNP) | VAF 58/142 reads (41%) | catalogued as rs752605638; called by muse, varscan2
- IGLV3-1 | c.333C>T p.S111= | Silent (SNP) | VAF 60/127 reads (47%) | catalogued as rs151220536; called by muse, varscan2
- LRRC8E | c.1753C>A p.R585= | Silent (SNP) | VAF 21/114 reads (18%) | catalogued as rs201776706; called by muse, mutect2, varscan2
- OTUB1 | c.126T>C p.A42= | Silent (SNP) | VAF 31/70 reads (44%) | called by muse, mutect2, varscan2
- RNF111 | c.345A>C p.I115= | Silent (SNP) | VAF 172/341 reads (50%) | called by muse, mutect2, varscan2
- SCAF8 | c.2439G>A p.L813= | Silent (SNP) | VAF 28/156 reads (18%) | called by muse, mutect2, varscan2
- SCAP | c.487C>T p.L163= | Silent (SNP) | VAF 64/133 reads (48%) | called by muse, mutect2, varscan2
- SYNJ2 | c.3639G>A p.P1213= | Silent (SNP) | VAF 70/142 reads (49%) | catalogued as rs375560899; called by muse, mutect2, varscan2
- TERF1 | c.69T>A p.P23= | Silent (SNP) | VAF 19/44 reads (43%) | called by muse, mutect2, varscan2
- ABCB9 | c.1053+933C>T | Intron (SNP) | VAF 67/140 reads (48%) | catalogued as rs1447028386; called by muse, mutect2, varscan2
- ARRB1 | c.*1365C>T | 3'UTR (SNP) | VAF 74/139 reads (53%) | called by muse, mutect2, varscan2
- ASB5 | c.197-16160C>A | Intron (SNP) | VAF 199/418 reads (48%) | called by muse, mutect2, varscan2
- CALHM5 | c.*4401C>T | 3'UTR (SNP) | VAF 33/73 reads (45%) | called by muse, mutect2, varscan2
- CCT6B | c.-34G>A | 5'UTR (SNP) | VAF 30/73 reads (41%) | called by muse, mutect2, varscan2
- CFAP43 | c.417-4456G>A | Intron (SNP) | VAF 4/22 reads (18%) | called by muse, mutect2
- CHRM3 | c.*5602T>C | 3'UTR (SNP) | VAF 56/180 reads (31%) | called by muse, mutect2, varscan2
- CORIN | c.*859T>G | 3'UTR (SNP) | VAF 26/130 reads (20%) | called by muse, mutect2, varscan2
- CREB3L4 | c.*4G>C | 3'UTR (SNP) | VAF 19/53 reads (36%) | called by muse, mutect2, varscan2
- DPP8 | c.*3115dup | 3'UTR (INS) | VAF 26/72 reads (36%) | catalogued as rs1170474124; called by mutect2, pindel, varscan2
- E2F3 | c.*94C>T | 3'UTR (SNP) | VAF 19/445 reads (4%) | called by muse, mutect2
- EMC2 | c.363+47A>G | Intron (SNP) | VAF 77/142 reads (54%) | called by muse, mutect2, varscan2
- EPB41L1 | c.*63C>T | 3'UTR (SNP) | VAF 58/162 reads (36%) | called by muse, mutect2, varscan2
- FAM20A | c.719+666A>C | Intron (SNP) | VAF 94/189 reads (50%) | called by muse, mutect2, varscan2
- FAM20C | c.864-17751G>A | Intron (SNP) | VAF 65/126 reads (52%) | catalogued as rs929462721; called by muse, mutect2, varscan2
- FRAS1 | c.-399C>T | 5'UTR (SNP) | VAF 24/152 reads (16%) | called by muse, mutect2, varscan2
- HARS1 | c.*269C>T | 3'UTR (SNP) | VAF 29/61 reads (48%) | called by muse, mutect2, varscan2
- IPCEF1 | c.*1467A>G | 3'UTR (SNP) | VAF 5/67 reads (7%) | called by muse, mutect2
- ITGB3BP | c.485-2857G>A | Intron (SNP) | VAF 25/46 reads (54%) | called by muse, mutect2, varscan2
- KALRN | c.451-37A>T | Intron (SNP) | VAF 137/296 reads (46%) | called by muse, mutect2, varscan2
- LINC02206 | n.253C>T | RNA (SNP) | VAF 57/115 reads (50%) | called by muse, mutect2, varscan2
- LINC02860 | n.1946G>T | RNA (SNP) | VAF 18/37 reads (49%) | called by muse, mutect2, varscan2
- LRP6 | c.*1244T>C | 3'UTR (SNP) | VAF 45/95 reads (47%) | called by muse, mutect2, varscan2
- LYRM1 | c.*3_*19del | 3'UTR (DEL) | VAF 87/278 reads (31%) | called by mutect2, pindel, varscan2
- MCF2L | c.459+1382C>T | Intron (SNP) | VAF 85/90 reads (94%) | catalogued as COSV100982426; called by muse, mutect2, varscan2
- MKRN9P | n.424C>A | RNA (SNP) | VAF 20/173 reads (12%) | called by muse, mutect2, varscan2
- MYEF2 | c.*2291G>A | 3'UTR (SNP) | VAF 29/88 reads (33%) | called by muse, mutect2, varscan2
- MYH10 | c.*1009C>T | 3'UTR (SNP) | VAF 48/92 reads (52%) | called by muse, mutect2, varscan2
- N4BP2L1 | c.308-85G>T | Intron (SNP) | VAF 115/119 reads (97%) | called by muse, mutect2, varscan2
- NCOA3 | c.*1937A>G | 3'UTR (SNP) | VAF 29/66 reads (44%) | called by muse, mutect2, varscan2
- NDUFA6 | chr22:42091063 G>A | 5'Flank (SNP) | VAF 12/29 reads (41%) | called by muse, varscan2
- NEDD4L | c.1126-16T>A | Intron (SNP) | VAF 67/135 reads (50%) | called by muse, mutect2, varscan2
- NYX | c.*265G>A | 3'UTR (SNP) | VAF 53/68 reads (78%) | catalogued as rs1387454126; called by muse, mutect2, varscan2
- OR51A4 | chr11:4944173 A>G | 3'Flank (SNP) | VAF 29/59 reads (49%) | called by muse, mutect2, varscan2
- PAM | c.*855G>T | 3'UTR (SNP) | VAF 37/68 reads (54%) | catalogued as rs563972836; called by muse, mutect2, varscan2
- PPFIA4 | c.*2162T>C | 3'UTR (SNP) | VAF 35/161 reads (22%) | called by mutect2, varscan2
- PREX2 | c.*4441G>A | 3'UTR (SNP) | VAF 26/50 reads (52%) | called by muse, mutect2, varscan2
- PRLR | c.*1079A>T | 3'UTR (SNP) | VAF 49/124 reads (40%) | called by muse, mutect2, varscan2
- PTPRE | c.1388-103A>T | Intron (SNP) | VAF 11/21 reads (52%) | called by muse, mutect2, varscan2
- RASGRF1 | c.*551C>T | 3'UTR (SNP) | VAF 46/102 reads (45%) | called by muse, mutect2, varscan2
- RNF38 | c.*362A>G | 3'UTR (SNP) | VAF 14/115 reads (12%) | called by muse, mutect2, varscan2
- SMYD5 | c.*457C>T | 3'UTR (SNP) | VAF 36/150 reads (24%) | called by muse, varscan2
- SNAPC3 | c.*2536A>T | 3'UTR (SNP) | VAF 49/99 reads (49%) | called by muse, mutect2, varscan2
- SNX3 | c.*559A>C | 3'UTR (SNP) | VAF 34/62 reads (55%) | called by muse, mutect2, varscan2
- SOX12 | c.*2628T>A | 3'UTR (SNP) | VAF 54/113 reads (48%) | called by muse, mutect2, varscan2
- STXBP6 | c.452-62G>A | Intron (SNP) | VAF 101/206 reads (49%) | catalogued as rs192572527; called by muse, mutect2, varscan2
- SYNPO | chr5:150657810 C>T | 3'Flank (SNP) | VAF 94/161 reads (58%) | catalogued as rs916953874; called by muse, mutect2, varscan2
- TCF7L1 | c.*730C>A | 3'UTR (SNP) | VAF 8/124 reads (6%) | called by muse, mutect2
- TGIF1 | c.*412A>G | 3'UTR (SNP) | VAF 23/57 reads (40%) | catalogued as COSV57908123; called by muse, mutect2, varscan2
- THSD4 | c.*4874T>C | 3'UTR (SNP) | VAF 8/68 reads (12%) | called by mutect2, varscan2
- TIMM23 | chr10:45972035 G>A | 5'Flank (SNP) | VAF 17/23 reads (74%) | called by muse, mutect2, varscan2
- UCK2 | c.259+28A>C | Intron (SNP) | VAF 46/240 reads (19%) | called by muse, mutect2, varscan2
- WNT9A | c.*2455G>A | 3'UTR (SNP) | VAF 18/210 reads (9%) | called by muse, mutect2
